Somatic mutation profile of tumor specimen TCGA-W5-AA33-01A (aliquot TCGA-W5-AA33-01A-11D-A417-09) from TCGA case TCGA-W5-AA33, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.5 years (22,090 days).
Specimen TCGA-W5-AA33-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53f84be4-d5b9-483b-858b-62c1368f8eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA33-10A (Blood Derived Normal), aliquot TCGA-W5-AA33-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a82d6a7f-b4ba-4d8a-ad43-7e29bf0ade9c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOC | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs1350997097; called by muse, mutect2
- CDH13 | c.960G>A p.E320= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as rs1408186185; called by muse, mutect2, varscan2
- CMA1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as rs755977857, COSV51625626; called by muse, mutect2, varscan2
- DEFB105A | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1466966442; called by mutect2, varscan2
- DNAH5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV54203290; called by muse, mutect2, varscan2
- NONO | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99338630; called by muse, mutect2
- PCDHA5 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as rs782665262, COSV65349338; called by muse, mutect2, varscan2
- PTPRG | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754335459, COSV55661669; called by muse, mutect2, varscan2
- SLC32A1 | c.92T>A p.M31K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54145653; called by muse, mutect2, varscan2
- SLC5A1 | c.1668C>G p.L556= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs1461301485; called by muse, mutect2
- USP9X | c.3449A>G p.N1150S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs377036436; called by muse, mutect2, varscan2
- ZYX | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV59557602; called by muse, mutect2, varscan2
- C11orf52 | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- CACNA1E | c.2630G>A p.G877D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- CDH20 | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAAF2 | c.2459A>C p.H820P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DSCAML1 | c.2317G>A p.V773M (on ENST00000321322; = p.V713M on NM_020693.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2
- EPHA2 | c.666_681del p.L223Afs*165 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- MPDZ | c.3080A>G p.D1027G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- PI15 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2
- POLR2B | c.3457_3486del p.Y1153_L1162del | In Frame Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- SMG6 | c.3830T>G p.L1277R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM1 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TRBV5-1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); called by muse, mutect2
- CCT8L2 | c.849C>A p.G283= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- DARS1 | c.1447T>C p.L483= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- ERMARD | c.1770G>C p.L590= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV64647484; called by muse, mutect2, varscan2
- TENM2 | c.6597G>A p.T2199= (on ENST00000518659 / NM_001122679.2; = p.T1960= on NM_001080428.3) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs540072530, COSV69137857; called by muse, mutect2, varscan2
- ZNF547 | c.279C>T p.S93= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776073 C>T | 5'Flank (SNP) | VAF 4/25 reads (16%) | catalogued as rs763081613, COSV50488445; called by muse, mutect2, varscan2
